Somatic mutation profile of tumor specimen TCGA-EM-A3AQ-01A (aliquot TCGA-EM-A3AQ-01A-11D-A20C-08) from TCGA case TCGA-EM-A3AQ, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 85.4 years (31,198 days).
Specimen TCGA-EM-A3AQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2bc2dd35-48fe-47f4-b744-66d65c623253.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A3AQ-10A (Blood Derived Normal), aliquot TCGA-EM-A3AQ-10A-01D-A20C-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b0cd6a3c-97e0-4e60-87ea-08a5a17f9ef3

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 7, Silent 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD24 | c.3073C>T p.Q1025* | Nonsense Mutation (SNP) | VAF 58/154 reads (38%) | catalogued as COSV53676426; called by muse, mutect2, varscan2
- ATAD2 | c.1658C>T p.S553F | Missense Mutation (SNP) | VAF 8/157 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54887958; called by muse, mutect2
- BEX1 | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65580867; called by muse, mutect2
- GTPBP4 | c.1606G>A p.D536N | Missense Mutation (SNP) | VAF 71/166 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1214764312, COSV52989416; called by muse, mutect2, varscan2
- RNF39 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 64/177 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV54994646; called by muse, mutect2, varscan2
- RPL10A | c.114G>T p.L38F | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57691291; called by muse, mutect2, varscan2
- SEL1L3 | c.2260A>G p.M754V | Missense Mutation (SNP) | VAF 26/288 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV53550980; called by muse, mutect2
- PRPF39 | c.1846G>C p.E616Q | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.009); called by muse, mutect2
- KCND2 | c.1080C>T p.A360= | Silent (SNP) | VAF 17/200 reads (9%) | catalogued as COSV58607571; called by muse, mutect2
- PRRC2B | c.3912C>A p.P1304= | Silent (SNP) | VAF 56/126 reads (44%) | catalogued as COSV61944215; called by muse, mutect2, varscan2
- TUBA8 | c.60C>T p.C20= | Silent (SNP) | VAF 66/142 reads (46%) | catalogued as COSV57814163; called by muse, mutect2, varscan2
